Somatic mutation profile of tumor specimen MMRF_1451_1_BM_CD138pos (aliquot MMRF_1451_1_BM_CD138pos_T1_KAS5U_L01601) from MMRF case MMRF_1451, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,860 days).
Specimen MMRF_1451_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a3e1ed9-a648-46e5-a5cf-ae4dee5c56dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1451_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1451_1_PB_Whole_C2_KAS5U_L01610; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51ca133-1415-4b8c-b15c-e2558eb1427e

The open-access MAF lists 236 somatic variants for this specimen: 92 protein-altering or splice-affecting, 29 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, 3'UTR 74, Silent 29, Intron 24, 5'UTR 6, Splice Site 5, Nonsense Mutation 5, RNA 4, 3'Flank 4, 5'Flank 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.2129G>A p.C710Y | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63024210; called by muse, mutect2, varscan2
- C5orf63 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); catalogued as rs752538265; called by muse, mutect2, varscan2
- CFAP57 | c.110A>G p.H37R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs767905897; called by muse, mutect2, varscan2
- CYYR1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54827898; called by muse, mutect2, varscan2
- DCDC1 | c.2127G>T p.M709I | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV60839976; called by muse, mutect2, varscan2
- DOCK3 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 54/111 reads (49%) | catalogued as rs775338280, COSV56513935; called by muse, mutect2, varscan2
- EEF2 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1212401; called by muse, mutect2
- HRNR | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs748726021, COSV100913661; called by muse, mutect2, varscan2
- IBTK | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 92/170 reads (54%) | catalogued as COSV60394750; called by muse, mutect2
- IGLC3 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | PolyPhen benign (0); catalogued as rs752091340; called by muse, mutect2, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, mutect2, varscan2
- IGLV4-60 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as rs768098610; called by muse, mutect2, varscan2
- LRCH4 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100052842; called by muse, mutect2
- MANSC1 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as rs1238928945; called by muse, mutect2, varscan2
- MON1A | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs1317549955; called by muse, mutect2, varscan2
- N4BP1 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52211023; called by muse, mutect2, varscan2
- PAK4 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV58947346; called by muse, mutect2, varscan2
- PCDHB1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV60629545; called by muse, mutect2, varscan2
- PIAS2 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs899626240; called by muse, mutect2, varscan2
- PLA2G4E | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV68152604; called by muse, mutect2, varscan2
- PPP1R9B | c.2107C>T p.R703W | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1056981216; called by muse, mutect2, varscan2
- PRKCB | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs781322629; called by muse, mutect2, varscan2
- RBP3 | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781921253; called by muse, mutect2, varscan2
- SDC3 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as rs1219433963; called by muse, mutect2, varscan2
- SVOP | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251162117; called by muse, mutect2, varscan2
- TCHH | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs772323685; called by muse, mutect2, varscan2
- TMPRSS6 | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.601); catalogued as rs1264412545, COSV60981588; called by muse, mutect2, varscan2
- WFDC10A | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 57/173 reads (33%) | catalogued as rs930661637; called by muse, mutect2, varscan2
- ZRANB2 | c.57-1G>C p.X19_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | catalogued as COSV54671159, COSV54671278; called by muse, mutect2
- ANKRD35 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ARNTL2 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRNL1 | c.3947G>A p.R1316K | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAAT | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- BCLAF3 | c.1419G>C p.Q473H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1orf185 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CACNA1A | c.3861T>G p.F1287L | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CWH43 | c.996G>T p.W332C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDN | c.1414A>C p.T472P | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSP | c.6829G>A p.A2277T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DUOXA1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERVV-2 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 115/164 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- F13B | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAH | c.193-2A>T p.X65_splice | Splice Site (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- FAM178B | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FNBP1 | c.157T>A p.Y53N | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FSIP2 | c.2248_2256del p.H750_P752del | In Frame Del (DEL) | VAF 43/89 reads (48%) | called by mutect2, varscan2
- FYTTD1 | c.656+2T>C p.X219_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2
- GTF3C2 | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- H1-2 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IBTK | c.1289G>T p.C430F | Missense Mutation (SNP) | VAF 94/172 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLC3 | c.312A>T p.E104D | Missense Mutation (SNP) | VAF 65/159 reads (41%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGLV5-45 | c.357C>G p.H119Q | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.187); called by muse, varscan2
- ING2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 125/273 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ITPR1 | c.7577A>G p.H2526R (on ENST00000354582; = p.H2471R on NM_002222.7) | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- KLRC1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- LPAR6 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- MOGAT3 | c.157T>C p.W53R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYBPC1 | c.2001G>A p.M667I (on ENST00000550270 / NM_206820.2; = p.M692I on NM_002465.4) | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NETO1 | c.512-2A>C p.X171_splice | Splice Site (SNP) | VAF 130/207 reads (63%) | called by muse, mutect2, varscan2
- NOL4 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- NTN1 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5AP2 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOL1 | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PHLDB3 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGB | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- POTEA | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PPP2R5E | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 76/79 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PRKY | c.720-13_723del p.X240_splice | Splice Site (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- RASAL3 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RASIP1 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RPL24 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RPL34 | c.249T>G p.C83W | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- RUNX2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, varscan2
- SAMSN1 | c.728C>G p.S243C (on ENST00000647101; = p.S15C on NM_001256370.1) | Missense Mutation (SNP) | VAF 17/584 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2
- SELENOP | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- SLC24A3 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- SMARCA2 | c.3230C>T p.S1077F | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- SRR | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TACR1 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBCK | c.959G>A p.R320K (on ENST00000273980 / NM_001163436.4; = p.R257K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TENT5C | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM39A | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TTC39B | c.1383T>G p.S461R | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TTN | c.62157T>A p.N20719K (on ENST00000591111; = p.N13295K on NM_003319.4) | Missense Mutation (SNP) | VAF 43/77 reads (56%) | PolyPhen probably damaging (0.91); called by muse, mutect2
- VCAM1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 66/70 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- YTHDC2 | c.1874T>C p.V625A | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZIC4 | c.929C>G p.S310W | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZNF449 | c.1396A>T p.N466Y | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF567 | c.1144C>G p.L382V (on ENST00000536254 / NM_001322913.1; = p.L351V on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ZPLD1 | c.1154G>T p.S385I (on ENST00000466937 / NM_001329788.1; = p.S401I on NM_175056.2) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- A4GALT | c.363C>T p.N121= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as rs1034139444, COSV99966798; called by muse, mutect2
- ACTG1 | c.90G>T p.V30= | Silent (SNP) | VAF 144/273 reads (53%) | called by muse, mutect2, varscan2
- BICRA | c.993C>T p.L331= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1194693763; called by muse, mutect2
- CCNK | c.627A>T p.A209= | Silent (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- CXCL1 | c.276A>T p.I92= | Silent (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- DDN | c.1413A>C p.R471= | Silent (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- DHRS7C | c.591C>T p.H197= (on ENST00000330255 / NM_001220493.2; = p.H196= on NM_001105571.3) | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs1555563044; called by muse, mutect2, varscan2
- GIPC3 | c.2607A>C p.T869= | Silent (SNP) | VAF 201/330 reads (61%) | catalogued as COSV59258574; called by muse, mutect2, varscan2
- HSDL1 | c.396C>T p.I132= | Silent (SNP) | VAF 13/97 reads (13%) | called by mutect2, varscan2
- IGLV7-46 | c.294T>A p.G98= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs769057802; called by muse, varscan2
- ITGAV | c.2298T>A p.L766= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53716324; called by muse, varscan2
- LRFN2 | c.1980C>T p.F660= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as rs372053737; called by muse, mutect2, varscan2
- MAP1B | c.3027G>A p.E1009= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV57102824; called by mutect2, varscan2
- MARCHF7 | c.1947G>A p.L649= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- MGAM | c.75C>T p.I25= | Silent (SNP) | VAF 111/224 reads (50%) | catalogued as rs1554452095; called by muse, mutect2, varscan2
- NEUROG3 | c.501G>A p.G167= | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- NPHP4 | c.2313C>T p.L771= | Silent (SNP) | VAF 107/180 reads (59%) | catalogued as rs372356993; called by muse, mutect2, varscan2
- PAPOLA | c.111A>T p.V37= | Silent (SNP) | VAF 47/63 reads (75%) | called by muse, mutect2, varscan2
- POGZ | c.2193C>G p.P731= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs770092722; called by muse, varscan2
- PPP1R12A | c.1167A>G p.Q389= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- PSD | c.945C>T p.I315= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as rs201335911; called by muse, mutect2, varscan2
- RECQL5 | c.2975G>A p.*992= | Silent (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2, varscan2
- RNF144A | c.594C>T p.C198= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs184927662; called by muse, mutect2, varscan2
- RPS6KA3 | c.2193T>G p.G731= | Silent (SNP) | VAF 132/132 reads (100%) | called by muse, mutect2, varscan2
- SPHK2 | c.813G>A p.V271= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs531500911; called by muse, mutect2, varscan2
- ST8SIA4 | c.90G>A p.E30= | Silent (SNP) | VAF 93/217 reads (43%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1389C>T p.P463= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- TOX4 | c.1287T>A p.A429= | Silent (SNP) | VAF 56/57 reads (98%) | catalogued as rs571846793, COSV52967500; called by muse, mutect2, varscan2
- ZNF618 | c.1467G>A p.G489= (on ENST00000374126 / NM_001318042.2; = p.G396= on NM_133374.2) | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- AC008676.3 | c.*860A>C | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- AC020637.1 | n.945C>A | RNA (SNP) | VAF 175/384 reads (46%) | catalogued as rs1039361483; called by muse, mutect2, varscan2
- AGBL2 | c.232+89G>A | Intron (SNP) | VAF 12/40 reads (30%) | called by muse, varscan2
- AHNAK | c.*235G>A | 3'UTR (SNP) | VAF 4/101 reads (4%) | called by muse, mutect2
- AKT2 | c.288-119C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- AMER1 | c.*1134_*1138dup | 3'UTR (INS) | VAF 65/93 reads (70%) | called by mutect2, pindel, varscan2
- AR | c.*5685del | 3'UTR (DEL) | VAF 46/63 reads (73%) | called by mutect2, pindel, varscan2
- ARHGAP23P1 | n.415C>A | RNA (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- ASB4 | c.*2432T>G | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- ASB8 | c.-33-332T>A | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- ATP5F1E | c.*4-463T>A | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- BMP8B | c.*1427T>C | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- BNIP3L | c.*2146G>C | 3'UTR (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- BRAF | c.*590G>C | 3'UTR (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- CAMK2N2 | c.*727C>T | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- CHML | c.*189G>A | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018848 G>A | 3'Flank (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- CHRM3 | c.*4310C>T | 3'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- CHSY3 | c.*2A>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- CRH | c.*63A>T | 3'UTR (SNP) | VAF 115/116 reads (99%) | called by muse, mutect2, varscan2
- CTNNB1 | c.*387A>C | 3'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- CUL3 | c.*378T>A | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- CX3CR1 | c.*1423T>A | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- CYP2S1 | c.*154G>C | 3'UTR (SNP) | VAF 75/124 reads (60%) | called by muse, mutect2, varscan2
- DCC | c.*3760A>C | 3'UTR (SNP) | VAF 51/135 reads (38%) | called by muse, mutect2, varscan2
- DHRS7B | c.-65T>A | 5'UTR (SNP) | VAF 33/74 reads (45%) | catalogued as rs1481203255; called by muse, mutect2, varscan2
- DSPP | c.*291A>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+1110C>T | Intron (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- ERBB4 | c.*1440T>C | 3'UTR (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- EVI2A | chr17:31317396 C>T | 3'Flank (SNP) | VAF 16/40 reads (40%) | called by muse, varscan2
- EXTL2 | c.-35A>G | 5'UTR (SNP) | VAF 65/65 reads (100%) | catalogued as rs953827967; called by muse, mutect2, varscan2
- FBXL17 | c.1965+1991T>C | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- FCGR3A | c.*914T>G | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- FSCN1 | c.*1130A>G | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- FUBP3 | c.*583C>T | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- GCSAML | c.*1514C>G | 3'UTR (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- GFOD1 | c.*5744G>A | 3'UTR (SNP) | VAF 38/80 reads (48%) | catalogued as rs554781453; called by muse, mutect2, varscan2
- GORASP2 | c.*45G>A | 3'UTR (SNP) | VAF 54/140 reads (39%) | called by muse, mutect2, varscan2
- GRIN1 | c.*752C>G | 3'UTR (SNP) | VAF 49/199 reads (25%) | called by muse, mutect2, varscan2
- H4C8 | chr6:26285573 T>C | 5'Flank (SNP) | VAF 78/408 reads (19%) | catalogued as rs1425047303; called by muse, mutect2, varscan2
- ICE2 | c.*2570T>G | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-60C>T | 5'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs574753732; called by muse, varscan2
- IMMP1L | c.322-57T>G | Intron (SNP) | VAF 202/413 reads (49%) | called by muse, mutect2, varscan2
- ING3 | c.*634T>G | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- ITIH5 | c.2032+180C>G | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- ITSN1 | c.*3999G>A | 3'UTR (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- KLF3 | c.*1970dup | 3'UTR (INS) | VAF 36/95 reads (38%) | catalogued as rs1359370794; called by mutect2, varscan2
- L3MBTL1 | c.2395-9C>T | Intron (SNP) | VAF 62/176 reads (35%) | called by muse, mutect2, varscan2
- LTBP3 | c.*121T>C | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- MAGEA10 | c.*70A>G | 3'UTR (SNP) | VAF 227/230 reads (99%) | called by muse, mutect2, varscan2
- MAGI2 | c.*1168G>A | 3'UTR (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- MAP3K1 | c.*2356A>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- MBNL3 | c.-30G>T | 5'UTR (SNP) | VAF 96/319 reads (30%) | catalogued as COSV63731794; called by muse, mutect2, varscan2
- MGAM | c.*163A>T | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- MTMR11 | c.*461G>A | 3'UTR (SNP) | VAF 70/220 reads (32%) | catalogued as COSV99641033; called by muse, mutect2, varscan2
- MUC19 | chr12:40421306 A>C | 3'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- MYCBPAP | c.1782+44G>A | Intron (SNP) | VAF 18/31 reads (58%) | catalogued as rs550381936, COSV60410347; called by muse, mutect2, varscan2
- MYSM1 | c.*3587C>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | catalogued as rs984632327; called by muse, mutect2, varscan2
- NAA15 | c.*1587T>C | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- NAGLU | c.*43G>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | catalogued as rs1261592619; called by muse, mutect2, varscan2
- NCAM2 | c.*3558T>A | 3'UTR (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- NELL2 | c.994+72C>A | Intron (SNP) | VAF 86/223 reads (39%) | called by muse, mutect2, varscan2
- NEURL4 | c.*428G>C | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- OBSCN | c.22958-141G>C | Intron (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2
- OS9 | c.*225G>A | 3'UTR (SNP) | VAF 73/122 reads (60%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*1562G>A | 3'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2
- PCDH15 | c.*2399G>A | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- PIGT | c.1401-37A>T | Intron (SNP) | VAF 102/246 reads (41%) | called by muse, mutect2, varscan2
- PKNOX1 | c.*3336T>C | 3'UTR (SNP) | VAF 47/77 reads (61%) | catalogued as rs1452558529; called by muse, varscan2
- PNRC2P1 | n.169C>A | RNA (SNP) | VAF 66/67 reads (99%) | called by muse, mutect2, varscan2
- PRKAR2A | c.-57C>G | 5'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- PSMD12 | c.*452T>C | 3'UTR (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- RAB11FIP2 | c.*1792T>A | 3'UTR (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- RCAN2 | c.*508G>A | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- RET | c.*573T>A | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- RGS4 | c.150-37G>C | Intron (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- RNF126P1 | n.1054G>C | RNA (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- SCN9A | c.*2168T>G | 3'UTR (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- SDHAF2 | c.36+45G>A | Intron (SNP) | VAF 51/124 reads (41%) | catalogued as rs760982958; called by muse, mutect2, varscan2
- SEPTIN7 | c.377+131T>C | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- SLAIN2 | c.1360+10820C>T | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SLC30A1 | c.*2921A>G | 3'UTR (SNP) | VAF 44/138 reads (32%) | catalogued as rs934577572; called by muse, mutect2, varscan2
- SLC35A1 | chr6:87472934 G>A | 5'Flank (SNP) | VAF 25/37 reads (68%) | called by muse, mutect2, varscan2
- SLTM | c.514-77C>T | Intron (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- SNX10 | c.*485C>T | 3'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- SOAT1 | c.*2836T>C | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, varscan2
- SOX2 | c.*334G>C | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15968441 G>A | 3'Flank (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- SPOPL | c.*1929C>T | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- SPRED1 | c.*2536G>A | 3'UTR (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- SSR2 | c.364-786A>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- SWAP70 | c.*2981T>C | 3'UTR (SNP) | VAF 76/184 reads (41%) | called by muse, mutect2, varscan2
- TAF8 | c.*4505G>A | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- TCAF1 | c.*2586G>A | 3'UTR (SNP) | VAF 30/1104 reads (3%) | catalogued as rs1357675375; called by muse, mutect2
- TLE1 | c.*99_*100del | 3'UTR (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- TMEM123 | c.*126A>T | 3'UTR (SNP) | VAF 20/241 reads (8%) | called by muse, mutect2
- TMEM132B | c.*7496T>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-221C>A | 5'UTR (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- TOLLIP | c.366+27G>C | Intron (SNP) | VAF 12/98 reads (12%) | called by mutect2, varscan2
- TPO | c.*958C>T | 3'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- TRIM22 | c.*401C>T | 3'UTR (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- TRIM52 | c.*801C>T | 3'UTR (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- TRIP11 | c.*1203A>T | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- TTC23 | c.*515G>A | 3'UTR (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2
- TTN | c.10303+2451C>T | Intron (SNP) | VAF 41/189 reads (22%) | catalogued as COSV100603189, COSV59910208; called by muse, mutect2, varscan2
- UNC5C | c.775+2063T>C | Intron (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- UPB1 | c.792-147C>G | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- VARS1 | c.*68C>A | 3'UTR (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- VPS35 | c.*74T>A | 3'UTR (SNP) | VAF 130/378 reads (34%) | called by muse, mutect2, varscan2
- WDR36 | c.*3298C>T | 3'UTR (SNP) | VAF 5/81 reads (6%) | catalogued as rs1474316863; called by muse, mutect2
- ZBTB37 | chr1:173865622 T>C | 5'Flank (SNP) | VAF 108/360 reads (30%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+4420C>T | Intron (SNP) | VAF 139/141 reads (99%) | called by muse, mutect2, varscan2
- ZNF772 | c.*2901T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs1044830885; called by muse, mutect2, varscan2
- ZNF813 | c.*937A>T | 3'UTR (SNP) | VAF 11/312 reads (4%) | called by muse, mutect2
- ZYG11B | c.*1686A>T | 3'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as rs995701384; called by muse, mutect2, varscan2
